Surgical pathology report (de-identified scan), TCGA case TCGA-28-2510, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Cedars Sinai, specimen TCGA-28-2510-01A (Primary Tumor).

CGA-28-2510

SURGICAL PATHOLOGY REPORT

***** Addendum - Please See End of Report *****

Reason for Addendum #1: Additional studies/stains/opinion(s)

DIAGNOSIS:

A. BRAIN, RIGHT FRONTAL, BIOPSY:

- Glioblastoma multiforme, WHO grade IV

B. BRAIN, RIGHT FRONTAL, EXCISIONAL BIOPSY, NCI#1:

- ~~Cortex and white matter~~

+ C. BRAIN, RIGHT FRONTAL, EXCISIONAL BIOPSY, NCI#2:

- Glioblastoma multiforme, WHO grade IV
- 2% of tumor necrosis
- 60% of tumor cellularity

D. BRAIN, RIGHT FRONTAL, EXCISIONAL BIOPSY, NCI#3:

- Glioblastoma multiforme, WHO grade IV
- 3% of tumor necrosis
- 60% of tumor cellularity

E. BRAIN, RIGHT FRONTAL, EXCISIONAL BIOPSY, NCI#4:

- Glioblastoma multiforme, WHO grade IV
- 10% of tumor necrosis
- 20% of tumor cellularity

F. BRAIN, RIGHT FRONTAL, EXCISIONAL BIOPSY, NCI#5:

- Glioblastoma multiforme, WHO grade IV
- 15% of tumor necrosis
- 20% of tumor cellularity

G. BRAIN, RIGHT FRONTAL, EXCISIONAL BIOPSY:

- Glioblastoma multiforme, WHO grade IV

COMMENT:

A high percentage of tumor cells (greater than 20%) immunostaining for MGMT has been reported to be associated with a relatively diminished response to Temodar. Hence, the 20% result in this case suggests the possibility of a relatively diminished response to Temodar.

Recent studies have shown that co-expression of EGFRvIII and PTEN as detected by immunostaining was significantly correlated with a clinical response of glioblastomas to EGFR kinase inhibitors. Hence the loss of PTEN in this case suggests a diminished probability of response to EGFR-kinase inhibitors.

Retained expression of PTEN was found to be associated with a more favorable prognosis in patients with high grade gliomas.

Source: NCI Genomic Data Commons file 2d4f2a9e-8040-4f07-859d-6458f2451ccd (TCGA-28-2510.BA885E83-E893-407B-B080-6C68F74B758E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).